CGCI case BLGSP-71-19-00118 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fad46708-bad8-4d20-991f-fba06cf7ae44

Demographics
Sex at birth: male; Race: white; Age at index: 18 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Classification of tumor: primary; Age at diagnosis: 18.7 years (6,825 days); Year of diagnosis: 2001; Method of diagnosis: Bone Marrow Aspirate; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,863 days (16.1 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, pediatric; Max tumor bulk site: Bone marrow; Sites of involvement: Bone marrow / Soft tissue / Colon, NOS / Small intestine / Pelvis.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary; Lymph nodes tested: 4.
   Pathology details: Lymph node involved site: Mesenteric.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 5,863 days (16.1 years); Disease response: Tumor Free.
- Follow-up contacts recording only the day: day 0, day 5,508.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD10: Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD20: Positive.
- CD3 (IHC): Negative.
- CD3: Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- Lactate Dehydrogenase 6975 [Blood test normal range upper: 770].

Other clinical attributes
- Day 0: Weight: 66.7 kg; Height: 175.6 cm; BMI: 21.6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-19-00118-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample BLGSP-71-19-00118-09A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.
  Slide BLGSP-71-19-00118-09A-01-S1-WG: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 15; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 40; Percent neutrophil infiltration: 40.
- Sample BLGSP-71-19-00118-16A: Sample type: Mononuclear Cells from Bone Marrow Normal; Tissue type: Normal; Specimen type: Mononuclear Cells from Bone Marrow; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Bone Marrow Aspirate; Tissue collection type: Retrospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- Primary pathology: Histologic diagnosis: ALL-L3 (small non-cleaved cell type); Extranodal site involvement: 5; Extranodal involvment other: pelvic mass, nos; Lymph nodes examined: Yes.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 6975.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD3.
